Surgical pathology report (de-identified scan), TCGA case TCGA-SQ-A6I6, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site International Genomics Consortium, specimen TCGA-SQ-A6I6-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB/Gender:

Location:

Soc. Sec. #:

Physician(s):

Path No.:

Client:

Collected:

Received:

Reported:

Hosp #:

Pre-Operative/Clinical History

Right adrenal tumor

Specimen(s) Received

A: RIGHT ADRENAL

Gross Description

The specimen is received fresh labeled adrenal, right:

Specimen type/description: Adrenal gland received fresh.

Procedure: Total adrenalectomy.

Specimen integrity: Intact.

Specimen size: 63 gm, 8.0 x 6.0 x 4.5 cm overall.

Specimen laterality: Right.

Tumor size: 5.0 cm.

Tumor description: A well-circumscribed solid, brown to yellow, focally hemorrhagic mass with no soft areas of necrosis identified. There is an eccentric 4.0 x 2. X 1.1 cm adrenal gland with central bright red hemorrhage and a thin bright yellow cortical rim.

Margins: The mass abuts the inked margin and is covered with a thin 0.1 cm capsule.

Treatment effect: Not identified.

A portion of the mass is submitted for frozen section analysis.

Gross photos are taken.

Representative sections are submitted as follows:

(A1 FS) Frozen section mass
(A2-A4) Mass and adjacent adrenal gland
(A5-A8) Mass to include inked margin.

Intraoperative Consultation

Specimen A, frozen section diagnosis of "pheochromocytoma" is rendered

ICD-O-3
Pheochromocytoma NOS
8700/3
R Adrenal gland NOS
C74.9
QW 6/12/13

Source: NCI Genomic Data Commons file 93e37c85-ef73-4958-9d0c-09c931b7a46a (TCGA-SQ-A6I6.50530B79-97AE-40A7-BEF5-B862569C42D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).